Somatic mutation profile of tumor specimen TCGA-DX-AB2V-01A (aliquot TCGA-DX-AB2V-01A-11D-A417-09) from TCGA case TCGA-DX-AB2V, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-AB2V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b2be2d9-1906-4807-8a19-d0b27d1cb391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2V-10A (Blood Derived Normal), aliquot TCGA-DX-AB2V-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0c9f7d0-7a67-492b-bc3d-cf3eeee03a2c

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Splice Site 4, Frame Shift Del 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STXBP2 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121918540, CM096296, COSV99657299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 161/199 reads (81%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- A1CF | c.1306C>A p.P436T (on ENST00000373993 / NM_138932.2; = p.P428T on NM_014576.4) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV50957440, COSV50964844; called by muse, mutect2, varscan2
- ACTBL2 | c.884A>C p.Y295S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101379393, COSV70661059; called by muse, mutect2, varscan2
- ADGRB1 | c.2225T>A p.F742Y | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100030112; called by muse, mutect2, varscan2
- AKAP6 | c.4049C>A p.A1350E | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99803071; called by muse, mutect2, varscan2
- C1QTNF2 | c.457C>T p.R153C (on ENST00000393975; = p.R108C on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs554501129, COSV67432492; called by muse, mutect2, varscan2
- C7orf31 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.476); catalogued as COSV99384083; called by muse, mutect2, varscan2
- CAPN11 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545825579, COSV101291925; called by muse, mutect2, varscan2
- CDH10 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as rs138533676; called by muse, mutect2, varscan2
- CDH19 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100051993; called by muse, mutect2, varscan2
- CDSN | c.915T>A p.S305R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV99457096; called by muse, mutect2, varscan2
- COL12A1 | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV59407957; called by muse, mutect2, varscan2
- CSE1L | c.2279+1G>A p.X760_splice | Splice Site (SNP) | VAF 20/104 reads (19%) | catalogued as COSV99522158; called by muse, mutect2, varscan2
- DENND2A | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.258); catalogued as COSV99326663; called by muse, mutect2, varscan2
- DOCK5 | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1407506156, COSV52406352; called by muse, mutect2, varscan2
- FDXR | c.1103A>G p.D368G (on ENST00000293195 / NM_024417.5; = p.D374G on NM_004110.6) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV99501276; called by muse, mutect2, varscan2
- FDXR | c.1102G>A p.D368N (on ENST00000293195 / NM_024417.5; = p.D374N on NM_004110.6) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs746364915, COSV99501277; called by muse, mutect2, varscan2
- FGD3 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs762399700, COSV61599710; called by muse, mutect2, varscan2
- FILIP1 | c.1040A>G p.E347G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99385688; called by muse, mutect2, varscan2
- FILIP1L | c.2452C>A p.L818M (on ENST00000354552 / NM_182909.3; = p.L578M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100497205, COSV100497528; called by muse, mutect2
- GIMAP8 | c.1610T>A p.F537Y | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as COSV100217626; called by muse, mutect2, varscan2
- GRIA1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1380820240, COSV53589953; called by muse, mutect2, varscan2
- GRIN1 | c.2432A>G p.E811G | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as COSV100160574; called by muse, mutect2, varscan2
- GZMK | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs200562138, COSV50246543; called by muse, mutect2, varscan2
- IFNE | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs147289613; called by muse, mutect2, varscan2
- JHY | c.400A>T p.S134C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV56217741, COSV56222406; called by muse, mutect2, varscan2
- KIFC3 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV101109292; called by muse, mutect2, varscan2
- KLHL4 | c.1886C>A p.A629D | Missense Mutation (SNP) | VAF 101/123 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100910063; called by muse, mutect2, varscan2
- KRTAP9-2 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100893220; called by muse, mutect2, varscan2
- KYNU | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); catalogued as rs142934146, COSV51587073; called by muse, mutect2, varscan2
- MAPT | c.162C>A p.D54E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.151); catalogued as COSV99291059; called by muse, mutect2, varscan2
- MUC16 | c.20789C>A p.T6930K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV101200655; called by muse, mutect2, varscan2
- MUC17 | c.360A>T p.E120D | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.176); catalogued as COSV100074480; called by muse, mutect2, varscan2
- NAPEPLD | c.506del p.P169Rfs*4 | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | catalogued as COSV58522681; called by mutect2, pindel, varscan2
- NCOR2 | c.2408C>T p.T803I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100657719; called by muse, mutect2, varscan2
- NCSTN | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV99667441; called by muse, mutect2, varscan2
- NIT1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63502465; called by muse, varscan2
- NLRP4 | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV100016817; called by muse, mutect2, varscan2
- PCDHA8 | c.2182A>C p.T728P | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.163); catalogued as COSV100969906; called by muse, mutect2, varscan2
- PEG3 | c.2851G>T p.V951L | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV99689890; called by muse, mutect2, varscan2
- POGZ | c.1683G>T p.K561N | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99653095; called by muse, mutect2, varscan2
- POLRMT | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99242159; called by muse, mutect2
- RNLS | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV100907483; called by muse, varscan2
- RYR3 | c.8728G>A p.V2910I (on ENST00000389232; = p.V2911I on NM_001036.6) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.42); catalogued as rs1295193017, COSV101213517; called by muse, mutect2, varscan2
- SCN9A | c.2632T>C p.F878L (on ENST00000303354; = p.F867L on NM_002977.3) | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57628567; called by muse, mutect2, varscan2
- SEL1L2 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99533661; called by muse, mutect2, varscan2
- SLC16A2 | c.368T>A p.I123N | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99330942; called by muse, mutect2, varscan2
- SLC44A1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.817); catalogued as rs540159903, COSV58262534; called by muse, varscan2
- SYCP2 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100698382; called by muse, mutect2, varscan2
- TBC1D1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs769775102, COSV99791850; called by mutect2, varscan2
- TXNRD1 | c.1639G>A p.E547K (on ENST00000525566 / NM_001093771.3; = p.E449K on NM_003330.4) | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV100723533, COSV61598226; called by muse, mutect2
- UGT3A2 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs778137539, COSV56934415, COSV99236693; called by muse, mutect2, varscan2
- UNC45B | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs770937125, COSV52102812; called by muse, mutect2, varscan2
- UPF2 | c.3289A>G p.I1097V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.768); catalogued as COSV100707388; called by muse, mutect2, varscan2
- VWF | c.3637A>G p.T1213A | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV99779737; called by muse, mutect2, varscan2
- ZDHHC15 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64903059; called by muse, mutect2, varscan2
- ZNF292 | c.7919A>G p.N2640S | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1489339545, COSV100370843; called by muse, mutect2
- ASIC2 | c.1240_1242del p.Y414del | In Frame Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- MASP1 | c.621del p.K208Rfs*69 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- SORL1 | c.4192_4213+22del p.X1398_splice | Splice Site (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel
- TBC1D32 | c.2478_2481+2del p.X826_splice | Splice Site (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel, varscan2
- ABCA13 | c.3318C>T p.H1106= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs1225800649, COSV101330131; called by muse, mutect2, varscan2
- ARHGAP30 | c.2163A>G p.K721= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV100920428; called by muse, mutect2, varscan2
- C9orf116 | c.189C>T p.Y63= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs369272868; called by muse, mutect2, varscan2
- CD1A | c.618C>T p.A206= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99192545; called by muse, varscan2
- CTBP2 | c.555C>T p.L185= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100456760; called by muse, mutect2, varscan2
- DPY19L3 | c.339C>T p.G113= | Silent (SNP) | VAF 61/354 reads (17%) | catalogued as rs1400588661, COSV100639258; called by muse, mutect2, varscan2
- ERICH3 | c.3498G>A p.S1166= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs200380141, COSV58616297; called by mutect2, varscan2
- FAM13A | c.2500C>T p.L834= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV52010027; called by muse, varscan2
- LAMA2 | c.291C>T p.H97= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV101370713; called by muse, mutect2, varscan2
- METTL25 | c.42C>G p.P14= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99810749; called by muse, mutect2, varscan2
- OR13C3 | c.855C>A p.I285= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV101053343; called by muse, mutect2, varscan2
- PAPPA2 | c.3531A>G p.V1177= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV100868415; called by muse, mutect2, varscan2
- PIM2 | c.795G>T p.R265= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as COSV99900395; called by muse, mutect2, varscan2
- RASGRF1 | c.1650C>T p.I550= | Silent (SNP) | VAF 33/208 reads (16%) | catalogued as rs756158411, COSV69176724; called by muse, mutect2, varscan2
- SALL3 | c.1944G>A p.P648= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs373055868, COSV73305969; called by muse, varscan2
- SEZ6L | c.2052C>T p.Y684= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs138699202; called by muse, mutect2, varscan2
- SLC4A3 | c.993C>T p.D331= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV99813081; called by muse, mutect2, varscan2
- TMEM163 | c.264A>T p.A88= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99926842; called by muse, mutect2, varscan2
- UTRN | c.9777A>G p.E3259= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100838698; called by muse, mutect2, varscan2
- ZNF25 | c.1296G>A p.G432= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100224728; called by muse, mutect2, varscan2
- ZPLD1 | c.876C>T p.V292= (on ENST00000466937 / NM_001329788.1; = p.V308= on NM_175056.2) | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100083443; called by muse, mutect2, varscan2
- NME1-NME2 | c.-5_-2del | 5'UTR (DEL) | VAF 17/156 reads (11%) | called by mutect2, pindel, varscan2
